Somatic mutation profile of tumor specimen MMRF_2141_1_BM_CD138pos (aliquot MMRF_2141_1_BM_CD138pos_T1_KHS5U_L08671) from MMRF case MMRF_2141, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.0 years (22,645 days).
Specimen MMRF_2141_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bba026e3-260e-4517-89b4-c454b20ae35d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2141_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2141_1_PB_Whole_C2_KHS5U_L08672; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea04b334-3654-4bcc-9ca1-84bbd366d88d

The open-access MAF lists 144 somatic variants for this specimen: 57 protein-altering or splice-affecting, 22 silent, 65 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, 3'UTR 39, Silent 22, Intron 13, RNA 6, 5'UTR 4, Nonsense Mutation 3, Splice Region 2, 3'Flank 2, Frame Shift Del 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 30/165 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67993216; called by muse, mutect2, varscan2
- ASAH2 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs141713369, COSV100270151; called by muse, mutect2, varscan2
- CENPP | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.707); catalogued as rs200767218; called by muse, mutect2, varscan2
- DGKZ | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 18/88 reads (20%) | catalogued as rs772985228; called by muse, mutect2, varscan2
- EIF2AK4 | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs192337360; called by muse, mutect2, varscan2
- EPS8L1 | c.2149G>A p.E717K (on ENST00000201647 / NM_133180.3; = p.E590K on NM_017729.3) | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV52386766; called by muse, mutect2
- H3C4 | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs780691617; called by muse, mutect2, varscan2
- HERC2 | c.8327G>A p.G2776D | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs1352578749, COSV55314693; called by muse, mutect2
- IGHV2-70 | c.342T>G p.Y114* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as rs370988849; called by muse, varscan2
- IGHV2-70D | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as rs1379651975; called by muse, varscan2
- IGKV1-5 | c.281C>G p.T94S | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.448); catalogued as rs374138816; called by muse, varscan2
- IGKV4-1 | c.235A>G p.T79A | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs369702177; called by muse, mutect2
- IGLV3-1 | c.132T>A p.D44E | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as rs373697673; called by muse, varscan2
- IGLV3-1 | c.191T>A p.L64Q | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as rs371723569; called by muse, varscan2
- MYH2 | c.3853C>A p.R1285S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as rs374494789; called by muse, mutect2, varscan2
- PARD6G | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1405301236, COSV62061431; called by muse, mutect2
- PHRF1 | c.3865C>A p.P1289T (on ENST00000264555 / NM_001286581.2; = p.P1288T on NM_020901.4) | Missense Mutation (SNP) | VAF 46/374 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV52760740; called by muse, mutect2, varscan2
- PLCH1 | c.3970G>C p.D1324H (on ENST00000340059 / NM_001130960.2; = p.D1316H on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.125); catalogued as COSV58200364; called by muse, mutect2, varscan2
- POMT2 | c.1018G>A p.G340S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778014493, COSV55070707; called by muse, mutect2, varscan2
- RNF41 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1488986658, COSV61504307; called by muse, mutect2
- RYR1 | c.3043C>T p.R1015C | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs139006437, COSV62099806; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC22A10 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs371483523; called by muse, mutect2, varscan2
- SNX2 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 34/276 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.82); catalogued as rs865871409; called by muse, mutect2, varscan2
- TFPI2 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757497424; called by muse, mutect2, varscan2
- USP2 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1189353019; called by muse, mutect2, varscan2
- ZNF107 | c.1624C>T p.H542Y | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs1174923038; called by muse, mutect2
- ADCY10 | c.1257G>A p.M419I | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ARID5B | c.1292A>C p.E431A | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2
- BCL11A | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- BCS1L | c.719+6T>A | Splice Region (SNP) | VAF 13/68 reads (19%) | called by muse, varscan2
- C18orf63 | c.1637C>G p.A546G | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- ENKUR | c.240del p.N81Tfs*10 | Frame Shift Del (DEL) | VAF 19/105 reads (18%) | called by mutect2, pindel, varscan2
- EP300 | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- FARP2 | c.120A>C p.Q40H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2
- FNTB | c.122A>G p.E41G | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GSE1 | c.426+1G>T p.X142_splice | Splice Site (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- HECW1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 38/141 reads (27%) | called by muse, mutect2, varscan2
- KLKB1 | c.959A>T p.E320V | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- LRP12 | c.2390A>G p.D797G | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- LRRIQ4 | c.557T>G p.V186G | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- MLXIPL | c.574-6C>T | Splice Region (SNP) | VAF 43/174 reads (25%) | called by muse, mutect2, varscan2
- NCBP2 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2
- NLRP5 | c.1734G>T p.E578D | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PLIN4 | c.3971A>C p.H1324P (on ENST00000301286; = p.H1339P on NM_001367868.2) | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PLXNC1 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.985); called by muse, mutect2
- PRPF18 | c.983A>C p.H328P | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); called by muse, mutect2
- RASEF | c.903G>T p.Q301H | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- RYR3 | c.8816C>A p.T2939N (on ENST00000389232; = p.T2940N on NM_001036.6) | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- SCAF1 | c.2444G>A p.S815N | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SPOCK3 | c.1271A>T p.D424V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- SPSB3 | c.957G>A p.M319I | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TBL1Y | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2
- TENM4 | c.6896G>A p.R2299H | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRBV4-1 | c.292C>A p.H98N | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- USH2A | c.6454A>G p.T2152A | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZNF793 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHI1 | c.1713A>T p.S571= | Silent (SNP) | VAF 13/156 reads (8%) | called by muse, mutect2
- AKAP12 | c.2892G>A p.T964= | Silent (SNP) | VAF 58/211 reads (27%) | catalogued as rs768500063; called by muse, mutect2, varscan2
- ALX1 | c.981A>G p.*327= | Silent (SNP) | VAF 8/208 reads (4%) | catalogued as rs1218152553; called by muse, mutect2
- ARHGEF16 | c.963C>A p.T321= | Silent (SNP) | VAF 9/201 reads (4%) | called by muse, mutect2
- ARL4C | c.321G>A p.E107= | Silent (SNP) | VAF 23/103 reads (22%) | called by muse, mutect2, varscan2
- ARPP21 | c.426G>A p.T142= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as rs756268326, COSV99491182, COSV99492673; called by muse, mutect2, varscan2
- C11orf95 | c.207G>A p.R69= | Silent (SNP) | VAF 9/164 reads (5%) | catalogued as rs1335085801, COSV58311692; called by muse, mutect2
- CEP170B | c.456C>T p.D152= (on ENST00000453495; = p.D82= on NM_015005.3) | Silent (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- ECEL1 | c.894C>T p.L298= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as rs1322791917; called by muse, mutect2, varscan2
- EFR3B | c.2436C>T p.P812= | Silent (SNP) | VAF 33/166 reads (20%) | catalogued as rs1205791698; called by muse, mutect2, varscan2
- GRAMD1B | c.720C>T p.D240= | Silent (SNP) | VAF 23/151 reads (15%) | catalogued as rs769186696; called by muse, mutect2, varscan2
- GRIN3B | c.1137C>T p.G379= | Silent (SNP) | VAF 71/180 reads (39%) | catalogued as rs373833586; called by muse, mutect2, varscan2
- HMMR | c.684T>G p.S228= | Silent (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.102A>G p.T34= | Silent (SNP) | VAF 8/31 reads (26%) | called by muse, varscan2
- LRRCC1 | c.3024C>T p.C1008= | Silent (SNP) | VAF 9/124 reads (7%) | called by muse, mutect2
- MYOF | c.3408C>T p.V1136= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs756700140, COSV63710006; called by muse, mutect2, varscan2
- OR8K5 | c.612A>T p.V204= | Silent (SNP) | VAF 32/139 reads (23%) | called by muse, mutect2, varscan2
- SBK1 | c.612C>T p.R204= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs1294016564, COSV59399403; called by muse, mutect2
- SLC22A13 | c.36T>C p.G12= | Silent (SNP) | VAF 12/176 reads (7%) | called by muse, mutect2
- TSPAN33 | c.135C>A p.V45= | Silent (SNP) | VAF 22/78 reads (28%) | called by muse, mutect2, varscan2
- VPS13B | c.11199C>T p.Y3733= | Silent (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- ZNF688 | c.519C>T p.S173= | Silent (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- ACTB | c.124-29C>T | Intron (SNP) | VAF 57/199 reads (29%) | catalogued as rs747012856; called by muse, mutect2, varscan2
- AMER3 | c.*1138G>A | 3'UTR (SNP) | VAF 13/72 reads (18%) | called by muse, mutect2, varscan2
- BEND5 | c.*173G>C | 3'UTR (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- C12orf77 | n.612+39A>G | Intron (SNP) | VAF 68/211 reads (32%) | called by muse, varscan2
- C20orf197 | n.1512A>G | RNA (SNP) | VAF 26/115 reads (23%) | called by muse, mutect2, varscan2
- CD177P1 | n.771A>C | RNA (SNP) | VAF 29/135 reads (21%) | called by muse, mutect2, varscan2
- CDR2L | c.*135G>A | 3'UTR (SNP) | VAF 7/103 reads (7%) | catalogued as rs1241276141; called by muse, mutect2
- CEMIP | c.1411+4774G>A | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- CHAC2 | c.-2A>T | 5'UTR (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2
- COL4A5 | c.3791-2833T>C | Intron (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- CYLC2 | c.*137G>A | 3'UTR (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- DCBLD2 | c.*1308G>T | 3'UTR (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- DHRS13 | c.*444T>G | 3'UTR (SNP) | VAF 31/106 reads (29%) | called by muse, mutect2, varscan2
- DUSP5 | c.*956T>C | 3'UTR (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- ELP4 | chr11:31788952 C>T | 3'Flank (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2, varscan2
- EPHA5 | c.-50C>T | 5'UTR (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- ETV1 | c.181+384C>T | Intron (SNP) | VAF 127/509 reads (25%) | catalogued as rs1253693207; called by muse, mutect2, varscan2
- FCGR2B | c.*400A>G | 3'UTR (SNP) | VAF 25/99 reads (25%) | called by muse, mutect2, varscan2
- FIGN | c.*3479A>C | 3'UTR (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- FPGT | c.*566T>G | 3'UTR (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- FSTL4 | c.1339+83C>A | Intron (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- FUNDC2P2 | n.408A>G | RNA (SNP) | VAF 4/82 reads (5%) | catalogued as rs1420177254; called by muse, mutect2
- HMGA1 | c.*1290C>T | 3'UTR (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- KCNF1 | c.*287C>A | 3'UTR (SNP) | VAF 19/94 reads (20%) | called by muse, mutect2, varscan2
- KCNQ1 | c.386+16094G>A | Intron (SNP) | VAF 15/68 reads (22%) | catalogued as rs777016344; called by muse, mutect2, varscan2
- KDM4E | c.*353G>T | 3'UTR (SNP) | VAF 36/62 reads (58%) | called by muse, mutect2, varscan2
- KIF1C | c.*2846T>C | 3'UTR (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- MEGF9 | c.*2659del | 3'UTR (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel, varscan2
- METTL9 | c.*2027C>T | 3'UTR (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- MID1IP1 | c.*638T>C | 3'UTR (SNP) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- MYO1E | c.-79T>C | 5'UTR (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- MYO1G | c.618+33T>C | Intron (SNP) | VAF 31/106 reads (29%) | called by muse, mutect2, varscan2
- NKX6-3 | c.*261G>A | 3'UTR (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- NRDE2 | c.*4099C>T | 3'UTR (SNP) | VAF 9/44 reads (20%) | catalogued as rs1208770609; called by muse, mutect2, varscan2
- NRG1 | c.503-6118A>T | Intron (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- PCDH15 | c.2868+644T>A | Intron (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- PCDH18 | c.*67dup | 3'UTR (INS) | VAF 31/131 reads (24%) | called by mutect2, pindel, varscan2
- PCDHB3 | c.*22G>T | 3'UTR (SNP) | VAF 16/398 reads (4%) | called by muse, mutect2
- PDE10A | c.*2677C>G | 3'UTR (SNP) | VAF 17/72 reads (24%) | called by mutect2, varscan2
- PDE10A | c.*2665_*2674dup | 3'UTR (INS) | VAF 12/66 reads (18%) | called by mutect2, varscan2
- PDXK | c.142+3140G>T | Intron (SNP) | VAF 46/105 reads (44%) | called by muse, mutect2, varscan2
- PHB2 | c.712-57G>A | Intron (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- PHC1P1 | n.1131G>A | RNA (SNP) | VAF 10/148 reads (7%) | catalogued as rs1341628781; called by muse, mutect2
- PIPSL | n.2286G>A | RNA (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2, varscan2
- PKD1L2 | c.*38C>T | 3'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- PLAG1 | c.*4450A>C | 3'UTR (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- PLAG1 | c.*1751T>G | 3'UTR (SNP) | VAF 6/35 reads (17%) | called by muse, varscan2
- PLAG1 | c.*1659T>C | 3'UTR (SNP) | VAF 8/58 reads (14%) | called by muse, varscan2
- PPARA | c.*2464T>C | 3'UTR (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- PRLR | c.*4186T>G | 3'UTR (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- QKI | c.935-592G>C | Intron (SNP) | VAF 31/84 reads (37%) | called by muse, mutect2, varscan2
- RHOB | c.*1159T>A | 3'UTR (SNP) | VAF 31/111 reads (28%) | called by muse, mutect2, varscan2
- RNF217 | c.*5428T>G | 3'UTR (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- SAR1B | c.*3921A>C | 3'UTR (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- SIGLEC7 | c.-26C>T | 5'UTR (SNP) | VAF 14/78 reads (18%) | catalogued as rs779965667; called by muse, mutect2, varscan2
- SLC39A8 | c.*1417C>T | 3'UTR (SNP) | VAF 7/45 reads (16%) | catalogued as rs1327408009; called by muse, mutect2, varscan2
- SLC6A3 | c.*1340G>A | 3'UTR (SNP) | VAF 16/70 reads (23%) | catalogued as rs751745477; called by muse, mutect2, varscan2
- SOX6 | chr11:15972107 T>A | 3'Flank (SNP) | VAF 28/101 reads (28%) | called by muse, mutect2, varscan2
- SYBU | c.*492G>A | 3'UTR (SNP) | VAF 37/105 reads (35%) | catalogued as rs1199060345; called by muse, mutect2, varscan2
- TMEM38B | c.*1222A>T | 3'UTR (SNP) | VAF 17/97 reads (18%) | called by muse, mutect2, varscan2
- TPM4 | c.*470A>G | 3'UTR (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- YIPF6 | chrX:68498850 G>A | 5'Flank (SNP) | VAF 35/90 reads (39%) | called by muse, mutect2, varscan2
- ZBTB18 | c.*1861G>A | 3'UTR (SNP) | VAF 30/98 reads (31%) | called by muse, mutect2, varscan2
- ZNF254 | c.*97T>G | 3'UTR (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- ZNF971P | n.717C>T | RNA (SNP) | VAF 32/107 reads (30%) | called by muse, mutect2, varscan2
